Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5G8, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5G8-01B (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site (R) Lung, upper lobe
C34.1

QAD 2/7/13

Histopathology Report

FINAL REPORT

HISTORY

Mass removed (lobectomy). ?Malignant.

MACROSCOPIC

Three specimens received

1: The specimen is labelled 'right upper lobe plus ribs' and consists of a right upper lobe measuring 180 x 105 x 45 mm. There is a vertical stapled line superior to the hilum measuring 80 mm in length. Over the apex there are two attached short segments of ribs. Rib 1 is relatively closely adhered over the pleural surface and measures 55 x 30 x 28 mm. This rib is cut towards one end, 22 mm from the true resection margin. Rib 2 loosely hangs from a fibrous fragment and measures 55 x 28 x 18 mm. Over the posterolateral aspect of the lung is a small segment of adherent parietal pleura measuring 30 x 25 mm. Within the apex, underlying the ribs is a firm white lesion measuring 25 x 25 x 23 mm. The mass shows focal central necrosis. The tumour is well clear of the hilar resection margin. The apical rib is removed and the underlying pleural surface is inked black. The true pleural margin is inked blue. The tumour appears to invade the pleura within this region, but does not extend into the overlying soft tissue. The remainder of the lung parenchyma shows severe emphysema with bullae in the apical aspect surrounding the tumour. No other focal lesions are seen or felt throughout the lobe. [1A, bronchial resection margin including vascular margin; 1B, hilar lymph node; 1C-F, RS of tumour mass; 1G, uninvolved lung, apex and base of lobe; 1H, peribronchial nodes; 1I, shave of soft tissue from attached rib; 1J, shave of soft tissue from loosely adhered rib; 1K-L, rep sections rib]

2: The specimen is labelled 'lymph node number 10' and consists of fragments of lymph node measuring 20 x 8 x 6 mm. [BIT: 2A]

3: The specimen is labelled 'fourth rib right' and consists of a rib fragment with attached soft tissue. The rib measures 12 x 17 x 7 mm. The attached soft tissue measuring 17 x 10 x 10 mm. No obvious lesion is identified within the specimen. [3A, soft tissue BIT; 3B, rib].

Please note that sections from the ribs in specimen 1 and 3 to follow.

MICROSCOPIC

1. Sections show a peripheral moderately-differentiated squamous cell carcinoma. There is pronounced desmoplasia and a central area of necrosis in association with the tumour. There is obliteration of the pleural space overlying the tumour due to adhesions and desmoplasia. It is difficult to interpret the layers but there is clear invasion through pleura and into chest wall. The involved fat appears to represent lipomatous metaplasia of pleura

[page 2 of 3]
Histopathology Report

rather than chest wall fat. Tumour does not extend as far as the muscle or bone and therefore the chest wall margin appears clear. The bronchial resection margin shows no evidence of in situ or invasive malignancy. No lymphatic, vascular or perineural invasion is seen. The sampled lymph nodes show sinus histiocytosis with moderate amounts of carbon pigment and no evidence of metastatic carcinoma. The surrounding lung parenchyma shows focal lipoid pneumonia and emphysema. Collections of smokers macrophages are present.

COMMENT

No sections of the ribs have been examined at this stage as the tissue is still being decalcified. Sections of the ribs will be examined in due course and a final report issued.

2. Sections of lymph node show sinus histiocytosis and a moderate amount of carbon pigment deposition and silicate crystals. There is no evidence of metastatic carcinoma.

3. Sections show normal intercostal muscle and adipose tissue. There is no evidence of invasive or metastatic carcinoma.

INTERIM SUMMARY

1 - 3. Right upper lobe of lung, ribs and No10 lymph node:

1: Moderately differentiated squamous cell carcinoma; 30 mm in maximal dimension.

2: No blood vessel, lymphatic or perineural invasion present.

3: Invasion into chest wall; clear of margins.

4: No lymph node metastases.

5: Pathological stage pT3N0Mx.

6: Rib sections still pending decalcification.

T-28000 M-80703 P1-03000

SUPPLEMENTARY REPORT -

The sections of rib have now been examined and these do not show any pathological features.

FINAL SUMMARY

1 - 3. Right upper lobe of lung, ribs and No10 lymph node:

1: Moderately differentiated squamous cell carcinoma; 30 mm in maximal

[page 3 of 3]
Histopathology Report

dimension.

- 2: No blood vessel, lymphatic or perineural invasion present.
- 3: Invasion into chest wall; clear of margins.
- 4: No lymph node metastases.
- 5: Pathological stage pT3N0Mx.

Reported

Source: NCI Genomic Data Commons file a2a8564b-a866-4285-af87-add3f491b69b (TCGA-77-A5G8.10343021-36C0-4188-A1DF-2CA02BF64CA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).